TARGET case TARGET-00-NAAENL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/b0443cf8-ac24-46ae-8cb2-36812d3a367b

Biospecimens (1 sample)
- Sample TARGET-00-NAAENL-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
